Gene-level copy-number profile of tumor specimen ALCH-AFJY-TTP1-A from ALCHEMIST case ALCH-AFJY, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 63.3 years (23,125 days).
Specimen ALCH-AFJY-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 005aefc2-57ca-41a5-9b49-802e509ff43d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AFJY-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,228 have no estimate.
https://portal.gdc.cancer.gov/files/beb765a0-96e6-40c7-8a95-79af273a3034

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 19; copy number 1: 135; copy number 2: 3,279; copy number 3: 3,863; copy number 4: 43,396; copy number 5: 2,393; copy number 6: 5,107; copy number 7: 203.

Homozygous deletions (total copy number 0; autosomes only): 19 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,638,285–22,029,594, 11 genes (within-gene range 0–3): H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,012,536, 3 genes (within-gene range 0–3): AL449423.1, CDKN2B, UBA52P6.
- chr9:61,615,835–61,642,494, 2 genes: FAM242D, Y_RNA.
- chr11:392,614–404,908, 1 gene: PKP3.
- chr14:18,333,726–18,343,144, 2 genes: CR383658.1, RNU6-458P.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 135. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
